Somatic mutation profile of tumor specimen TCGA-DJ-A4UW-01A (aliquot TCGA-DJ-A4UW-01A-11D-A257-08) from TCGA case TCGA-DJ-A4UW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.4 years (12,563 days).
Specimen TCGA-DJ-A4UW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf844645-7a94-4f73-b767-36117fc8b740.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4UW-10A (Blood Derived Normal), aliquot TCGA-DJ-A4UW-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9054a119-1694-4c0a-981b-724ff8990feb

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- APC | c.5140G>T p.D1714Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); catalogued as CM045451, COSV57358636, COSV57367668; called by muse, mutect2, varscan2
- NSD1 | c.4463A>G p.N1488S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV61778829, COSV61781513; called by muse, mutect2, varscan2
- OR10X1 | c.767C>A p.T256N | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63767781, COSV63767822; called by muse, mutect2
- PSMB1 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303286485, COSV100079857, COSV51530054; called by muse, mutect2
- RCVRN | c.514T>C p.F172L | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56842165; called by muse, mutect2, varscan2
- TSPYL1 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV63994235; called by muse, mutect2, varscan2
- GLA | c.330T>G p.P110= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as rs781967285, COSV54510225; called by muse, mutect2
- MAPKBP1 | c.3021C>T p.C1007= (on ENST00000456763 / NM_001128608.2; = p.C1001= on NM_014994.3) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV52965701; called by muse, mutect2, varscan2
